Gene-level copy-number profile of tumor specimen TCGA-DD-A113-01A from TCGA case TCGA-DD-A113, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 55.3 years (20,188 days).
Specimen TCGA-DD-A113-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.adba634e-5124-4ec6-bc81-3b0c77e56ba3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A113-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b63807ff-1669-42c4-b4fd-5b62321ebfaf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 5,303; copy number 3: 22,061; copy number 4: 6,899; copy number 5: 17,994; copy number 6: 4,184; copy number 7: 145; copy number 8: 2,596; copy number 9: 570; copy number 10: 54; copy number 14: 12; copy number 22: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A113-01A-11D-A12Y-01): tumor purity 0.7, ploidy 4.03, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:130,573,996–130,574,112, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,378 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–226,412,135, 2,040 genes, copy number 8 (broad region; genes not listed).
- chr1:226,781,501–248,919,946, 556 genes, copy number 8 (broad region; genes not listed).
- chr13:106,541,673–114,337,626, 145 genes, copy number 7 (broad region; genes not listed).
- chr19:11,296,139–11,914,329, 42 genes, copy number 10 (within-gene range 3–10): TSPAN16, AC011472.2, RAB3D, AC011472.3, TMEM205, CCDC159, PLPPR2, AC024575.1, SWSAP1, EPOR, RGL3, Y_RNA, CCDC151, PRKCSH, ELAVL3, AC008481.3, ZNF653, MIR7974, ECSIT, RN7SL833P, AC008481.2, AC008481.1, CNN1, ELOF1, ZNF627, ACP5, GAPDHP76, AC008543.1, ZNF887P, HNRNPA1P10, ZNF833P, ZNF823, AC008543.3, AC008543.2, ZNF441, AC008543.5, ZNF491, ZNF440, AC008543.4, ZNF439, AC020951.1, ZNF69.
- chr19:12,995,475–13,098,796, 1 gene, copy number 9 (within-gene range 3–9): NFIX.
- chr19:13,069,792–22,532,485, 477 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr20:2,101,827–4,249,287, 76 genes, copy number 9 (broad region; genes not listed).
- chr20:52,671,735–56,299,160, 41 genes, copy number 9–22: AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
